Somatic mutation profile of tumor specimen TCGA-CH-5762-01A (aliquot TCGA-CH-5762-01A-11D-1576-08) from TCGA case TCGA-CH-5762, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.4 years (22,068 days).
Specimen TCGA-CH-5762-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34b7c874-8884-4e11-83f0-80ba04a1c59c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5762-11A (Solid Tissue Normal), aliquot TCGA-CH-5762-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94efa757-2d2d-4257-90db-fbf45a81b0c9

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Frame Shift Del 3, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMY1A | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100915770; called by mutect2, varscan2
- ATM | c.5015G>C p.G1672A | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV53733204, COSV53781901; called by muse, mutect2, varscan2
- BFSP1 | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV64902357; called by muse, mutect2, varscan2
- C10orf99 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV64531854, COSV64532313; called by muse, mutect2
- C19orf57 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58786812; called by muse, mutect2, varscan2
- CDH19 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs538411423, COSV50983698; called by muse, mutect2, varscan2
- CYB5R4 | c.1239G>C p.L413F | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770132881, COSV63752633; called by muse, mutect2, varscan2
- DACT1 | c.1601A>G p.E534G | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV60024025; called by muse, mutect2, varscan2
- DDHD1 | c.2012A>G p.N671S (on ENST00000323669; = p.N868S on NM_030637.3) | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.001); catalogued as COSV60363455; called by muse, mutect2, varscan2
- DGAT1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1554847558, COSV60048754; called by muse, mutect2, varscan2
- EEF1A2 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1415254392, COSV53208803; called by muse, mutect2
- EIF2AK3 | c.2894A>T p.D965V | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV57553139; called by muse, mutect2, varscan2
- ELAPOR2 | c.2261G>A p.G754E (on ENST00000450689 / NM_001142749.3; = p.G587E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51893047; called by muse, mutect2, varscan2
- ELAPOR2 | c.2167G>A p.E723K (on ENST00000450689 / NM_001142749.3; = p.E556K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV51889812, COSV51893064; called by muse, mutect2
- FAM98C | c.548A>T p.H183L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV53040113; called by muse, mutect2, varscan2
- FAT1 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV71676379; called by muse, mutect2, varscan2
- FREM1 | c.2187G>T p.M729I | Missense Mutation (SNP) | VAF 80/464 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV66524150, COSV66532000; called by muse, varscan2
- FSCN3 | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50002285; called by muse, mutect2, varscan2
- FZD5 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV54944925; called by muse, mutect2
- GPRIN3 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV60886782; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs747773579; called by mutect2, varscan2
- HAPLN4 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.544); catalogued as COSV52271829; called by muse, mutect2, varscan2
- HNF4G | c.77C>A p.A26E (on ENST00000354370 / NM_001330561.2; = p.A73E on NM_004133.5) | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62974897; called by muse, mutect2, varscan2
- ICA1L | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV64175681; called by muse, mutect2, varscan2
- IPO8 | c.1286A>T p.K429M | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV56246968; called by muse, varscan2
- IPO8 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); catalogued as COSV56246976; called by muse, varscan2
- KRT4 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs372301476; called by muse, mutect2, varscan2
- LIMK2 | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV59185186; called by muse, mutect2, varscan2
- LRFN4 | c.1600A>C p.T534P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58923304; called by muse, mutect2
- MASP2 | c.1228T>A p.Y410N | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68897813; called by muse, mutect2, varscan2
- MIS18BP1 | c.2599C>A p.P867T | Missense Mutation (SNP) | VAF 8/239 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1307821961, COSV60374106; called by muse, mutect2
- MUC16 | c.13325C>G p.T4442R | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.592); catalogued as COSV67451445, COSV67502341; called by muse, mutect2
- NPAS2 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs774483099, COSV59563433; called by muse, mutect2, varscan2
- PDE1C | c.1529G>C p.W510S | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58532606; called by muse, mutect2, varscan2
- PLEKHA8 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV51656292; called by muse, mutect2, varscan2
- POLG | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51526147; called by muse, mutect2
- PTPN13 | c.2660C>T p.S887L | Missense Mutation (SNP) | VAF 16/495 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs894444879, COSV57402244; called by muse, mutect2
- RAE1 | c.678C>G p.N226K | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV64799187; called by muse, mutect2, varscan2
- RIPK2 | c.1585T>C p.S529P | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV55134975, COSV55135483; called by muse, mutect2
- RUNX1T1 | c.683A>G p.D228G (on ENST00000265814 / NM_001198628.1; = p.D201G on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56166711; called by muse, mutect2
- SNX31 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 54/417 reads (13%) | catalogued as COSV61265525; called by muse, mutect2, varscan2
- SRRD | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV53226841, COSV53228149; called by muse, mutect2, varscan2
- STK17A | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 50/456 reads (11%) | catalogued as rs149915695, COSV60048394; called by muse, mutect2, varscan2
- TMC1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV52771782; called by muse, mutect2, varscan2
- CHD3 | c.1939dup p.Y647Lfs*13 | Frame Shift Ins (INS) | VAF 23/213 reads (11%) | called by mutect2, pindel, varscan2
- SLC20A1 | c.1946del p.N649Tfs*35 | Frame Shift Del (DEL) | VAF 32/269 reads (12%) | called by mutect2, pindel, varscan2
- TRPA1 | c.3099_3105del p.I1033Mfs*6 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, pindel, varscan2
- ZNF264 | c.856_864del p.P286_K288del | In Frame Del (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel
- ADGRF2 | c.1950G>A p.K650= (on ENST00000296862 / NM_001368115.2; = p.K582= on NM_153839.7) | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV57292908; called by muse, mutect2
- CHFR | c.1509G>A p.P503= (on ENST00000432561 / NM_001161345.1; = p.P462= on NM_018223.2) | Silent (SNP) | VAF 61/382 reads (16%) | catalogued as rs142511371; called by muse, mutect2, varscan2
- CILP | c.57G>T p.V19= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs1376782765, COSV56028758; called by muse, mutect2, varscan2
- DDIT4 | c.288G>A p.L96= | Silent (SNP) | VAF 49/498 reads (10%) | catalogued as rs778797662, COSV56578229; called by muse, mutect2
- DNAH12 | c.1164G>A p.V388= | Silent (SNP) | VAF 49/285 reads (17%) | catalogued as rs757484307, COSV60859495; called by muse, mutect2, varscan2
- FGD3 | c.1554A>C p.A518= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV61600514; called by muse, varscan2
- GAB3 | c.927C>G p.P309= | Silent (SNP) | VAF 18/203 reads (9%) | catalogued as COSV65821013; called by muse, mutect2
- KIF1B | c.96C>T p.G32= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV55817899; called by muse, mutect2, varscan2
- LIMS2 | c.561G>T p.L187= (on ENST00000355119 / NM_001161403.3; = p.L211= on NM_017980.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV55757565; called by muse, mutect2, varscan2
- MED13L | c.732G>A p.P244= | Silent (SNP) | VAF 67/240 reads (28%) | catalogued as rs1359784128, COSV56132849; called by muse, mutect2, varscan2
- NLGN4X | c.1482C>G p.P494= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs146227486, COSV52041347, COSV99321338; called by muse, varscan2
- NPAS4 | c.2007C>T p.D669= | Silent (SNP) | VAF 55/371 reads (15%) | catalogued as rs1362874294, COSV60652670; called by muse, mutect2, varscan2
- TAS2R46 | c.579A>T p.I193= | Silent (SNP) | VAF 40/358 reads (11%) | catalogued as COSV67863659; called by muse, varscan2
- USP35 | c.1032C>T p.F344= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs781090025, COSV71572604, COSV71573344; called by muse, mutect2, varscan2
- TESK2 | c.-1T>G | 5'UTR (SNP) | VAF 12/114 reads (11%) | catalogued as COSV100517009; called by muse, mutect2
